Somatic mutation profile of tumor specimen TARGET-30-PARJMX-01A (aliquot TARGET-30-PARJMX-01A-01D) from TARGET case TARGET-30-PARJMX, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.5 years (903 days).
Specimen TARGET-30-PARJMX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c09d47e-c75d-4610-bc92-9b66ff2bb4a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARJMX-10A (Blood Derived Normal), aliquot TARGET-30-PARJMX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/397d1cb5-c083-4aa9-97dd-06424435913c

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs144025957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IKZF4 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56269567; called by muse, mutect2, varscan2
- MPL | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.505); catalogued as COSV65245416; called by muse, mutect2, varscan2
- TRIM55 | c.1555C>G p.Q519E | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as COSV52542228; called by muse, mutect2, varscan2
- TRIO | c.3224C>T p.T1075I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60082952; called by muse, mutect2
- CYP1A1 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CYP1A1 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2
- MED1 | c.25+1G>A p.X9_splice | Splice Site (SNP) | VAF 36/287 reads (13%) | called by muse, mutect2, varscan2
- QTRT2 | c.801A>G p.G267= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
